Gene-level copy-number profile of tumor specimen C3N-05114-01 (profiled together with C3N-05114-02) from CPTAC case C3N-05114, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.5 years (24,283 days).
Specimen C3N-05114-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8e6d7605-891f-46c6-a8a1-6fd577f4b1a5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-05114-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/7b84e754-0bcc-4a8b-8f2d-64a1716d507e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 3,410; copy number 2: 51,735; copy number 3: 2,553; copy number 4: 82; copy number 5: 36; copy number 6: 232; copy number 7: 150; copy number 8: 84; copy number 10: 37; copy number 39: 3; copy number 44: 7; copy number 48: 1; copy number 52: 2; copy number 57: 6; copy number 89: 2.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,502,265–23,438,700, 66 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 560 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,872,982–53,366,066, 1 gene, copy number 6 (within-gene range 2–6): SCFD2.
- chr4:53,265,461–55,125,595, 33 genes, copy number 6: RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR.
- chr7:53,316,149–63,211,822, 162 genes, copy number 5–89 (broad region; genes not listed).
- chr7:63,326,674–69,125,376, 193 genes, copy number 5–48 (broad region; genes not listed).
- chr7:69,187,833–69,189,318, 1 gene, copy number 8: AC069280.1.
- chr7:116,672,196–117,874,139, 37 genes, copy number 10: MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2.
- chr7:128,207,872–132,087,992, 133 genes, copy number 6–8 (within-gene range 6–49) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,066. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
